Somatic mutation profile of tumor specimen MP2PRT-PARMGR-TMP1-A (aliquot MP2PRT-PARMGR-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARMGR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,820 days).
Specimen MP2PRT-PARMGR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22c17f23-10ba-4c5e-aebe-8ff0f9b35441.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARMGR-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARMGR-NM1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f51b5660-bf9d-4298-aaba-565008653779

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 13, Nonsense Mutation 2, Silent 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS5 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1238632042, COSV54752696; ClinVar: likely pathogenic; called by muse, varscan2
- CARD14 | c.1360C>T p.Q454* | Nonsense Mutation (SNP) | VAF 30/727 reads (4%) | catalogued as COSV60123669; called by muse, mutect2
- CASQ2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs200265771; ClinVar: uncertain significance; called by muse, mutect2
- DLGAP2 | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 438/1244 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70101213; called by muse, varscan2
- MAGI2 | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 162/472 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752723914, COSV62641661; called by muse, varscan2
- NOSTRIN | c.950C>G p.S317* (on ENST00000317647 / NM_001039724.4; = p.S239* on NM_052946.3) | Nonsense Mutation (SNP) | VAF 14/394 reads (4%) | catalogued as rs748351263, COSV58319357; called by muse, mutect2
- POMGNT1 | c.354G>A p.T118= | Splice Region (SNP) | VAF 109/380 reads (29%) | catalogued as rs1262087747, COSV100915463; called by muse, mutect2, varscan2
- ASAH1 | c.157C>G p.P53A | Missense Mutation (SNP) | VAF 69/396 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- CDH5 | c.1067G>A p.R356K | Missense Mutation (SNP) | VAF 129/485 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRM5 | c.2256G>C p.L752F | Missense Mutation (SNP) | VAF 136/577 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- IGBP1 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 142/272 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, varscan2
- PAX5 | c.615_616delinsCGCTGATCA p.E205Dfs*40 | Frame Shift Ins (INS) | VAF 129/449 reads (29%) | called by pindel, varscan2*
- PRDM5 | c.609C>A p.N203K | Missense Mutation (SNP) | VAF 106/358 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SFMBT1 | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 24/526 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.149); called by muse, mutect2
- STAC2 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 37/878 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- ZNF160 | c.1897A>T p.N633Y | Missense Mutation (SNP) | VAF 215/635 reads (34%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ZNF711 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 89/141 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MMP15 | c.1704A>G p.R568= | Silent (SNP) | VAF 342/1027 reads (33%) | catalogued as rs1269739408; called by muse, mutect2, varscan2
- RASD1 | c.84C>T p.V28= | Silent (SNP) | VAF 198/787 reads (25%) | called by muse, varscan2
